Surgical pathology report (de-identified scan), TCGA case TCGA-14-0817, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0817-01A (Primary Tumor).

[page 1 of 4]
AP Report

* Final Report *

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info:
14-0817

* Final Report *

Anatomic Pathology Report

Patient:
Patient Number:
Financial Number:
Room/Bed:
Admitting Physician:
Ordering Physician:

Accession Number:
Date Collected:
Date Received:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, RIGHT TEMPORAL, CRANIOTOMY, FS1A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
2. BRAIN, MEDIAL RIGHT TEMPORAL, CRANIOTOMY, FS2A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
3. BRAIN, RIGHT TEMPORAL, CRANIOTOMY:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

SPECIMEN:

1. Right temporal brain lesion,
2. Medial right temporal tumor,
3. Right temporal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

with right brain lesion.

NAME OF OPERATION: Right craniotomy for tumor resection.

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
AP Report

* Final Report *

PREOPERATIVE DIAGNOSIS: Right brain lesion.

POSTOPERATIVE DIAGNOSIS: Right brain lesion.

GROSS DESCRIPTION:

The specimen is received in three parts. Specimens #1-2 are received fresh for intraoperative consultation and specimen #3 is received in formalin, each labeled with the patient's name and hospital number.

Specimen #1 is labeled "right temporal brain lesion." The specimen consists of multiple irregular fragments of soft, tan-pink, focally hemorrhagic tissue, measuring 1.3 x 1.1 x 0.3 cm in aggregate. One half of the specimen is submitted for frozen section evaluation with the remaining cryoblock resubmitted as "FS1A." The entire remaining portion of tissue is submitted in one additional cassette, "1B."

Specimen #2 is labeled "medial right temporal tumor." The specimen consists of fragments of soft, tan-pink tissue, measuring 0.7 x 0.6 x 0.2 cm in aggregate. The entire portion of tissue is submitted for frozen section evaluation with the remaining cryoblock resubmitted as "FS2A."

Specimen #3 is labeled "right temporal brain lesion." The specimen consists of multiple irregular fragments of soft, tan-pink, focally hemorrhagic tissue, measuring 2.3 x 2.2 x 0.4 cm in aggregate. The specimen is entirely submitted in two cassettes, "3A" through "3D."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT TEMPORAL BRAIN LESION (FROZEN SECTION, TOUCH PREPARATION):
GLIOBLASTOMA MULTIFORME.

FS2A, TP2A: MEDIAL RIGHT TEMPORAL TUMOR (FROZEN SECTION, TOUCH PREPARATION):
GLIOBLASTOMA MULTIFORME.

[page 3 of 4]
[REDACTED]

AP Report

* Final Report *

Patient: [REDACTED]

Accession Number: [REDACTED]

Patient N [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

TISSUE COMMITTEE CODE:

1

14-0817

[REDACTED]

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.2

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 3 of 4
(Continued)

[page 4 of 4]
AP Report

* Final Report *

Page 2 (End of Report)

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file 2520e047-20a4-46eb-82eb-9906fe7993b1 (TCGA-14-0817.C93C85D6-FDA0-4AED-8846-624FA502EE41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).